Somatic mutation profile of tumor specimen TCGA-DJ-A4V4-01A (aliquot TCGA-DJ-A4V4-01A-11D-A257-08) from TCGA case TCGA-DJ-A4V4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 48.9 years (17,878 days).
Specimen TCGA-DJ-A4V4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b618a54-8bb5-48c8-b38e-49f606eb164b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4V4-10A (Blood Derived Normal), aliquot TCGA-DJ-A4V4-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c993e286-b313-403f-b153-9c6ccb8d5a64

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABAT | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as COSV51621450; called by muse, mutect2
- AFTPH | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.443); catalogued as COSV53216696; called by muse, varscan2
- ASPDH | c.490G>A p.A164T (on ENST00000389208 / NM_001114598.2; = p.A59T on NM_001024656.3) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.201); catalogued as COSV65349533; called by muse, mutect2
- CRB1 | c.2064C>G p.I688M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV66329148; called by muse, mutect2, varscan2
- CUL3 | c.1611G>T p.R537S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100024938, COSV52362755; called by muse, mutect2
- DSCAML1 | c.4027G>T p.E1343* (on ENST00000321322; = p.E1283* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV58385650, COSV58404521; called by muse, mutect2, varscan2
- HELB | c.1056C>A p.F352L | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56073022, COSV56073404; called by muse, mutect2
- KAT6B | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV54744338; called by muse, mutect2
- PPP1R7 | c.858C>G p.I286M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52144044; called by muse, mutect2, varscan2
- RABGAP1 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV65379705; called by muse, mutect2
- RAPGEF1 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV64698617; called by muse, mutect2, varscan2
- SLC35B1 | c.394C>G p.L132V (on ENST00000649906; = p.L95V on NM_005827.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV53602479; called by muse, mutect2, varscan2
- SPINK5 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56250197, COSV56250809; called by muse, mutect2, varscan2
- WDPCP | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55415706, COSV99706457; called by muse, mutect2, varscan2
- ABR | c.2163C>G p.L721= (on ENST00000302538 / NM_021962.5; = p.L684= on NM_001092.5) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs200483424, COSV52143373; called by muse, mutect2
- CYP17A1 | c.246C>A p.A82= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV64004814; called by muse, mutect2, varscan2
- MTMR12 | c.156T>C p.L52= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV53783161; called by muse, mutect2, varscan2
- TP53BP1 | c.2886G>A p.E962= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs1178863086, COSV55498229; called by muse, mutect2
